Somatic mutation profile of tumor specimen TCGA-B8-5551-01A (aliquot TCGA-B8-5551-01A-01D-1534-10) from TCGA case TCGA-B8-5551, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 65.6 years (23,976 days).
Specimen TCGA-B8-5551-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f799234a-8685-46c0-a125-eae699701585.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-5551-10A (Blood Derived Normal), aliquot TCGA-B8-5551-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3b8be46-3647-4999-ac14-a217acd4afaf

The open-access MAF lists 52 somatic variants for this specimen: 36 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 15, Frame Shift Del 5, Nonsense Mutation 3, Splice Site 1, Frame Shift Ins 1, Intron 1, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.397A>C p.T133P | Missense Mutation (SNP) | VAF 70/412 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as rs1131690961, CD983002, COSV56542355, COSV56546113, COSV56573642; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC090517.4 | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 194/1339 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1181936770, COSV50995644; called by muse, mutect2, varscan2
- BAP1 | c.67+1G>A p.X23_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | catalogued as CS165257, COSV56229828, COSV56233365; called by muse, mutect2, varscan2
- CCDC33 | c.733C>G p.R245G | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as rs757090698, COSV58347636, COSV58348905; called by muse, mutect2
- CLDND2 | c.366C>G p.N122K | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV52466980, COSV52468318; called by muse, mutect2, varscan2
- DUSP26 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.074); catalogued as rs1292100733, COSV56360576; called by muse, mutect2
- EIF2B5 | c.1183G>A p.D395N (on ENST00000647909; = p.D387N on NM_003907.3) | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV56603511; called by muse, mutect2, varscan2
- FAT4 | c.5096A>T p.E1699V | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67880613; called by muse, mutect2, varscan2
- GNB5 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 36/536 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV55897630; called by muse, mutect2
- GPATCH8 | c.3097T>C p.S1033P | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59192916; called by muse, mutect2, varscan2
- HHATL | c.1438G>A p.V480I | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.033); catalogued as rs918851737, COSV55132397; called by muse, mutect2, varscan2
- HIP1R | c.1351A>T p.K451* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as COSV53438760; called by muse, mutect2, varscan2
- KIAA0100 | c.652A>G p.T218A | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs1460484525, COSV66490261; called by muse, mutect2
- L1CAM | c.3422G>T p.C1141F | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62826549; called by muse, mutect2, varscan2
- LAMA1 | c.5770C>A p.H1924N | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV67531033; called by muse, mutect2, varscan2
- LAMP5 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 32/188 reads (17%) | catalogued as COSV55714893; called by muse, mutect2, varscan2
- LTA4H | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 76/601 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV57381434; called by muse, mutect2, varscan2
- MECP2 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV57651470; called by muse, mutect2
- MYO18A | c.5919C>A p.D1973E | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV62861884; called by muse, mutect2, varscan2
- NKRF | c.512A>T p.Q171L | Missense Mutation (SNP) | VAF 48/312 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV58660476; called by muse, varscan2
- OR10H1 | c.745G>C p.V249L | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58470562; called by muse, mutect2, varscan2
- PLCB4 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 47/366 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV53791301; called by muse, mutect2
- PLCH1 | c.1800A>C p.E600D (on ENST00000340059 / NM_001130960.2; = p.E612D on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as COSV58184760; called by muse, mutect2, varscan2
- RYR3 | c.11584C>G p.L3862V (on ENST00000389232; = p.L3863V on NM_001036.6) | Missense Mutation (SNP) | VAF 20/530 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66776021; called by muse, mutect2
- SERPINB6 | c.709A>C p.I237L (on ENST00000612421 / NM_001271823.2; = p.I218L on NM_004568.6) | Missense Mutation (SNP) | VAF 36/598 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as COSV59564690; called by muse, mutect2
- SERPINF2 | c.679A>G p.T227A | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV60663401; called by muse, mutect2
- ZNF33B | c.1876C>T p.Q626* | Nonsense Mutation (SNP) | VAF 27/232 reads (12%) | catalogued as COSV63941727; called by muse, mutect2, varscan2
- ZNF790 | c.227C>A p.P76Q | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as COSV63211856; called by muse, mutect2, varscan2
- COQ10A | c.421del p.V141Sfs*30 | Frame Shift Del (DEL) | VAF 22/145 reads (15%) | called by mutect2, pindel, varscan2
- GPRC5C | c.1047_1048insTCC p.T349_K350insS (on ENST00000652232; = p.T304_K305insS on NM_018653.4) | In Frame Ins (INS) | VAF 6/70 reads (9%) | called by mutect2, pindel
- IGF1R | c.2287_2298del p.Y763_T766del | In Frame Del (DEL) | VAF 16/150 reads (11%) | called by mutect2, pindel
- NR1D2 | c.1670del p.K557Sfs*8 | Frame Shift Del (DEL) | VAF 38/252 reads (15%) | called by mutect2, pindel, varscan2
- POM121 | c.3653_3654del p.G1218Vfs*? (on ENST00000434423; = p.G953Vfs*110 on NM_172020.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 33/286 reads (12%) | called by mutect2, pindel, varscan2
- RARS1 | c.1813del p.A605Qfs*24 | Frame Shift Del (DEL) | VAF 24/179 reads (13%) | called by mutect2, pindel, varscan2
- SV2C | c.1899dup p.S634Ifs*22 | Frame Shift Ins (INS) | VAF 64/518 reads (12%) | called by mutect2, pindel, varscan2
- USP28 | c.1219_1220del p.N407* | Frame Shift Del (DEL) | VAF 166/968 reads (17%) | called by mutect2, pindel, varscan2
- CAPZA3 | c.393C>T p.D131= | Silent (SNP) | VAF 44/291 reads (15%) | catalogued as rs1335758375, COSV56848292; called by muse, mutect2, varscan2
- CCND2 | c.576T>C p.F192= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as COSV54221404; called by muse, mutect2, varscan2
- CYP2C19 | c.213G>A p.L71= | Silent (SNP) | VAF 116/1008 reads (12%) | catalogued as COSV64906607; called by muse, mutect2, varscan2
- GALNT13 | c.1419A>G p.K473= | Silent (SNP) | VAF 24/741 reads (3%) | catalogued as COSV67208519; called by muse, mutect2
- HIP1R | c.1350G>C p.L450= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV53438743; called by muse, mutect2, varscan2
- IL22 | c.273G>T p.L91= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as COSV60159656; called by muse, mutect2, varscan2
- MBTPS1 | c.2088G>A p.V696= | Silent (SNP) | VAF 16/179 reads (9%) | catalogued as rs1206587680, COSV58569089; called by muse, mutect2
- MTMR6 | c.1179C>T p.V393= | Silent (SNP) | VAF 12/338 reads (4%) | catalogued as COSV67807717; called by muse, mutect2
- PCDHB1 | c.1125C>T p.D375= | Silent (SNP) | VAF 47/262 reads (18%) | catalogued as rs1554267277, COSV60629287; called by muse, mutect2, varscan2
- TAAR6 | c.855C>A p.G285= | Silent (SNP) | VAF 12/352 reads (3%) | catalogued as COSV51582479, COSV99256695; called by muse, mutect2
- TBCEL | c.1044C>A p.V348= | Silent (SNP) | VAF 16/328 reads (5%) | catalogued as COSV52458302; called by muse, mutect2
- TMEM17 | c.387C>A p.L129= | Silent (SNP) | VAF 58/290 reads (20%) | catalogued as COSV59022266; called by muse, mutect2, varscan2
- TNRC18 | c.8490C>T p.A2830= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs755774307, COSV60305882; called by muse, mutect2, varscan2
- UNC45B | c.2727A>G p.E909= | Silent (SNP) | VAF 25/265 reads (9%) | catalogued as rs1369550115, COSV52091617; called by muse, mutect2
- ZCCHC2 | c.1521G>A p.K507= | Silent (SNP) | VAF 58/846 reads (7%) | catalogued as COSV54035822; called by muse, mutect2
- CAMK2A | c.985-982A>C | Intron (SNP) | VAF 43/307 reads (14%) | catalogued as COSV62244808; called by muse, mutect2, varscan2
